Gene-level copy-number profile of tumor specimen TCGA-95-7947-01A from TCGA case TCGA-95-7947, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 67.8 years (24,752 days).
Specimen TCGA-95-7947-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.cb160b5c-e035-4478-9b25-ea6626cb32f8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-95-7947-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/48a107d1-46ba-4623-8bcc-fa18469309ec

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 28; copy number 1: 12,265; copy number 2: 34,947; copy number 3: 10,375; copy number 4: 1,579; copy number 5: 372; copy number 6: 47; copy number 7: 74; copy number 8: 105; copy number 13: 1; copy number 14: 4; copy number 28: 15.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-95-7947-01A-11D-2183-01): tumor purity 0.66, ploidy 2.07, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 28 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:22,090,743–22,706,703, 28 genes: UBBP4, FTLP13, LINC02002, AC138761.1, AC138761.2, FAM27E5, AC087575.1, FLJ36000, AC132825.3, AC132825.4, MTND6P35, MTCYBP13, MTRNR2L1, AC132825.2, MTND1P15, MTND2P13, AC132825.1, NMTRS-TGA3-1, MTATP6P3, MTCO3P13, AC132825.6, AC132825.7, AC132825.5, AC131055.2, AC131055.1, AC131274.3, AC131274.1, AC131274.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 618 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:33,440,696–34,158,767, 15 genes, copy number 6 (within-gene range 4–6): TARS1, TOMM40P3, AC034232.1, ADAMTS12, RNU6-923P, RXFP3, SLC45A2, AC139783.2, AMACR, C1QTNF3-AMACR, AC139783.1, C1QTNF3, AC139792.2, AC139792.3, AC139792.1.
- chr7:20,134,655–20,217,404, 1 gene, copy number 7 (within-gene range 2–7): MACC1.
- chr7:20,217,577–28,180,795, 170 genes, copy number 5–8 (within-gene range 3–8) (broad region; genes not listed).
- chr9:80,357,029–83,069,143, 32 genes, copy number 6: NPAP1P4, MTCO1P51, MTND2P9, RPS19P6, AL138749.1, RPS20P25, AL161727.1, TLE1, AL591368.1, RNU6-1035P, RNA5SP287, AL158154.1, SPATA31D5P, AL158154.2, SPATA31D4, AL158154.3, SPATA31D3, SPATA31D2P, AL162726.3, SPATA31D1, SPATA31B1P, DDX10P2, AL158047.1, AL162726.1, MTCO3P40, AL162726.2, AL162726.4, AL356490.1, AL353774.1, RPS6P12, RASEF, AL499602.1.
- chr9:89,563,537–96,147,856, 156 genes, copy number 5 (broad region; genes not listed).
- chr10:58,869,184–59,363,181, 7 genes, copy number 7 (within-gene range 4–7): RN7SKP196, LINC00844, RPLP1P10, TRAF6P1, PHYHIPL, FAM13C, AC025038.1.
- chr10:60,026,298–60,733,490, 1 gene, copy number 7 (within-gene range 4–7): ANK3.
- chr10:60,684,505–60,794,852, 3 genes, copy number 7: ARL4AP1, ANK3-DT, CDK1.
- chr10:63,110,139–64,693,446, 17 genes, copy number 8–14 (within-gene range 1–14): RNU6-543P, AL590502.1, NRBF2, JMJD1C, TATDN1P1, AC022022.2, MIR1296, PRELID1P3, JMJD1C-AS1, AC022022.1, REEP3, AC022387.2, MRPL35P2, AC013287.1, RPL7AP50, AC012558.1, DBF4P1.
- chr17:38,702,262–39,864,312, 61 genes, copy number 7–28 (within-gene range 2–28) (broad region; genes not listed).
- chr18:47,390–8,406,861, 155 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 9,879. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
